Somatic mutation profile of tumor specimen TCGA-FZ-5919-01A (aliquot TCGA-FZ-5919-01A-11D-1609-08) from TCGA case TCGA-FZ-5919, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 59.2 years (21,611 days).
Specimen TCGA-FZ-5919-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15270174-c28f-4e64-bfa0-9fe5d9685591.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FZ-5919-11A (Solid Tissue Normal), aliquot TCGA-FZ-5919-11A-02D-1609-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0975f03-bb05-4def-8a7d-e4b2de0bf952

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 20, Silent 8, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 22/148 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>C p.V173L | Missense Mutation (SNP) | VAF 37/295 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; called by muse, mutect2, varscan2
- AACS | c.1346A>C p.N449T | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99907849; called by muse, mutect2, varscan2
- APOBR | c.2891G>A p.G964D (on ENST00000431282; = p.G973D on NM_018690.4) | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV100112902; called by muse, mutect2, varscan2
- CLCNKA | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.158); catalogued as COSV58893141; called by muse, mutect2
- COL2A1 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 25/294 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs1373299848, COSV100477378; called by muse, mutect2
- CPM | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 53/484 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763585354, COSV58035351; called by muse, mutect2, varscan2
- DCHS1 | c.3575G>A p.S1192N | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.921); catalogued as COSV100202534; called by muse, mutect2
- DCT | c.1290C>A p.Y430* | Nonsense Mutation (SNP) | VAF 37/295 reads (13%) | catalogued as COSV100986296; called by muse, mutect2, varscan2
- ENPP5 | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 48/1452 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100040592; called by muse, mutect2
- FERMT1 | c.460A>C p.K154Q | Missense Mutation (SNP) | VAF 27/592 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.864); catalogued as COSV99452059; called by muse, mutect2
- GLI3 | c.2965C>T p.R989W | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs1313713644, COSV101230022, COSV67894033; called by muse, mutect2, varscan2
- GNE | c.2117A>G p.Y706C (on ENST00000396594 / NM_001128227.3; = p.Y675C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/264 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100930132; called by muse, mutect2
- HMGB4 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 63/679 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); catalogued as rs369597433; called by muse, mutect2
- LRRN2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs1161577749, COSV100912947; called by muse, mutect2
- MAGT1 | c.595A>T p.I199F (on ENST00000618282 / NM_001367916.1; = p.I231F on NM_032121.5) | Missense Mutation (SNP) | VAF 36/550 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1191465689, COSV100800426; called by muse, mutect2
- NRROS | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs1459933887, COSV60747901; called by muse, mutect2
- PCSK1N | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV99504899; called by muse, mutect2
- SPTBN2 | c.6644C>T p.P2215L | Missense Mutation (SNP) | VAF 60/597 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100020349; called by muse, mutect2, varscan2
- TTN | c.4169C>T p.P1390L (on ENST00000591111; = p.P1344L on NM_003319.4) | Missense Mutation (SNP) | VAF 18/364 reads (5%) | PolyPhen possibly damaging (0.606); catalogued as rs144011561, COSV100618097; ClinVar: uncertain significance; called by muse, mutect2
- ZNF618 | c.2489G>T p.C830F (on ENST00000374126 / NM_001318042.2; = p.C737F on NM_133374.2) | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99930979; called by muse, mutect2, varscan2
- ATXN7L2 | c.891G>A p.E297= | Silent (SNP) | VAF 12/292 reads (4%) | catalogued as COSV100881365; called by muse, mutect2
- COG3 | c.1176A>T p.T392= | Silent (SNP) | VAF 17/189 reads (9%) | catalogued as COSV100596728; called by muse, mutect2
- HECW1 | c.3549C>T p.Y1183= | Silent (SNP) | VAF 47/457 reads (10%) | catalogued as rs367579167; called by muse, mutect2, varscan2
- MEX3B | c.1572C>T p.S524= | Silent (SNP) | VAF 23/471 reads (5%) | catalogued as rs755726923, COSV61662938; called by muse, mutect2
- PSG6 | c.732C>A p.T244= | Silent (SNP) | VAF 93/1094 reads (9%) | catalogued as COSV99414489; called by muse, mutect2
- RAD17 | c.93C>T p.G31= (on ENST00000380774 / NM_133339.2; = p.G20= on NM_002873.1) | Silent (SNP) | VAF 50/399 reads (13%) | catalogued as rs755672631, COSV99281742; called by muse, mutect2, varscan2
- SLC6A5 | c.2187C>T p.I729= | Silent (SNP) | VAF 28/892 reads (3%) | catalogued as COSV100117119; called by muse, mutect2
- TTLL9 | c.1143C>T p.V381= | Silent (SNP) | VAF 50/500 reads (10%) | catalogued as rs377006514, COSV60590655; called by muse, mutect2
